Somatic mutation profile of tumor specimen TARGET-15-SJMPAL044957-09A (aliquot TARGET-15-SJMPAL044957-09A-01D) from TARGET case TARGET-15-SJMPAL044957, project TARGET-ALL-P3 (Acute Lymphoblastic Leukemia - Phase III). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 17.0 years (6,211 days).
Specimen TARGET-15-SJMPAL044957-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 34a01721-1e9d-48b2-8414-15236d10a8f8.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-15-SJMPAL044957-15A (Fibroblasts from Bone Marrow Normal), aliquot TARGET-15-SJMPAL044957-15A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/8eb5b7a4-3fba-4354-ab3c-21af18040eb5

The open-access MAF lists 8 somatic variants for this specimen: 5 protein-altering or splice-affecting, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 5, Intron 1, 3'UTR 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CASKIN2 | c.278G>T p.G93V | Missense Mutation (SNP) | VAF 4/43 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by mutect2, varscan2
- OR14A2 | c.433G>T p.V145F | Missense Mutation (SNP) | VAF 3/35 reads (9%) | SIFT tolerated (0.17); PolyPhen benign (0.165); called by muse, mutect2
- PDK2 | c.1108C>A p.R370S | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT tolerated (0.42); PolyPhen benign (0.222); called by mutect2, varscan2
- PTPRE | c.1266C>A p.D422E | Missense Mutation (SNP) | VAF 5/56 reads (9%) | SIFT tolerated (0.28); PolyPhen benign (0.001); called by muse, mutect2
- UBTF | c.774G>T p.E258D | Missense Mutation (SNP) | VAF 6/48 reads (13%) | SIFT tolerated (0.52); PolyPhen benign (0.013); called by muse, mutect2
- GLYCTK | c.*1726_*1727dup | 3'UTR (INS) | VAF 6/53 reads (11%) | catalogued as rs780634197; called by mutect2, varscan2
- MIR1-1HG-AS1 | n.796G>T | RNA (SNP) | VAF 3/20 reads (15%) | called by muse, mutect2
- ZBTB17 | c.535+131G>T | Intron (SNP) | VAF 3/27 reads (11%) | called by muse, mutect2
